Somatic mutation profile of tumor specimen C3L-00606-02 (aliquot CPT0079280009) from CPTAC case C3L-00606, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 75.7 years (27,636 days).
Specimen C3L-00606-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6bfb262a-9f48-4437-90f4-0fbb02e22866.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00606-31 (Blood Derived Normal), aliquot CPT0080110002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbe85b59-7c76-4812-a19f-a67e106d4a46

The open-access MAF lists 72 somatic variants for this specimen: 49 protein-altering or splice-affecting, 14 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 14, Frame Shift Del 10, Intron 4, Splice Site 3, Nonsense Mutation 2, 3'UTR 2, 5'UTR 1, Frame Shift Ins 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.463+1G>C p.X155_splice | Splice Site (SNP) | VAF 69/187 reads (37%) | hotspot (GDC flag); catalogued as rs869025657, CS004297, CS111451, CS961708, COSV56543633, COSV56544194, COSV56546569, COSV56552736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.1844G>A p.R615H | Missense Mutation (SNP) | VAF 62/287 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs547878738, COSV60911544, COSV60913298; called by muse, mutect2, varscan2
- FAR1 | c.1193C>T p.S398F | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV61385256; called by muse, varscan2
- GALNTL6 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 54/220 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV72552982; called by muse, mutect2, varscan2
- KCNQ5 | c.2707_2708del p.L903Kfs*13 | Frame Shift Del (DEL) | VAF 62/300 reads (21%) | catalogued as rs779394238; called by pindel, varscan2
- KIF3C | c.1614G>T p.M538I | Missense Mutation (SNP) | VAF 41/211 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs748213434; called by muse, mutect2, varscan2
- MED1 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV56127912; called by muse, mutect2, varscan2
- MRC1 | c.2920C>T p.R974* | Nonsense Mutation (SNP) | VAF 52/293 reads (18%) | catalogued as rs1367320854; called by muse, mutect2, varscan2
- PCDH12 | c.451C>T p.R151* | Nonsense Mutation (SNP) | VAF 13/76 reads (17%) | catalogued as rs1175979418, COSV99190845; called by muse, mutect2, varscan2
- SLC2A9 | c.311A>G p.D104G | Missense Mutation (SNP) | VAF 64/272 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs773926335; called by muse, mutect2, varscan2
- TALDO1 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 75/339 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as rs893159233, COSV59797685; called by muse, mutect2, varscan2
- TAPBPL | c.1082G>A p.G361D | Missense Mutation (SNP) | VAF 77/327 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781465778; called by muse, mutect2, varscan2
- TGFBR3 | c.1387G>A p.V463M | Missense Mutation (SNP) | VAF 49/209 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1440465103, COSV53025131; called by muse, mutect2, varscan2
- YIPF3 | c.158T>C p.L53P | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as rs1554131040; called by muse, mutect2, varscan2
- AHCTF1 | c.2170T>A p.L724M (on ENST00000366508; = p.L698M on NM_015446.5) | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANHX | c.146G>T p.S49I | Missense Mutation (SNP) | VAF 124/485 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ANKRD42 | c.996C>G p.D332E | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ANPEP | c.2067_2070del p.E689Dfs*10 | Frame Shift Del (DEL) | VAF 55/192 reads (29%) | called by mutect2, pindel, varscan2
- ATP6V1C1 | c.63del p.K21Nfs*23 | Frame Shift Del (DEL) | VAF 33/147 reads (22%) | called by mutect2, pindel, varscan2
- ATXN10 | c.1213T>C p.C405R | Missense Mutation (SNP) | VAF 74/321 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- C1QB | c.519del p.S174Lfs*7 | Frame Shift Del (DEL) | VAF 52/256 reads (20%) | called by mutect2, pindel, varscan2
- C2CD6 | c.244del p.T82Lfs*12 | Frame Shift Del (DEL) | VAF 7/47 reads (15%) | called by mutect2, pindel, varscan2
- CASP4 | c.178T>A p.S60T | Missense Mutation (SNP) | VAF 68/299 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- CLCN1 | c.2291G>C p.R764T | Missense Mutation (SNP) | VAF 79/365 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DBN1 | c.1717C>A p.Q573K | Missense Mutation (SNP) | VAF 144/397 reads (36%) | SIFT tolerated (0.89); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DCAF7 | c.914A>T p.D305V | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- DST | c.8029T>A p.L2677I | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- EDEM2 | c.149_162del p.Y50Ffs*5 | Frame Shift Del (DEL) | VAF 22/213 reads (10%) | called by mutect2, pindel, varscan2
- FBXO25 | c.1056_1068del p.F353Lfs*23 (on ENST00000382824 / NM_183421.2; = p.F277Lfs*23 on NM_012173.3) | Frame Shift Del (DEL) | VAF 24/180 reads (13%) | called by mutect2, pindel, varscan2
- HECW1 | c.3753-15_3763del p.X1251_splice | Splice Site (DEL) | VAF 16/82 reads (20%) | called by mutect2, pindel
- HSPBP1 | c.-94-1G>C | Splice Site (SNP) | VAF 67/326 reads (21%) | called by muse, mutect2, varscan2
- IREB2 | c.1607T>C p.L536P | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LHX3 | c.290T>A p.I97N (on ENST00000371748 / NM_178138.6; = p.I102N on NM_014564.5) | Missense Mutation (SNP) | VAF 65/237 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LINGO4 | c.961del p.H321Mfs*3 | Frame Shift Del (DEL) | VAF 52/241 reads (22%) | called by mutect2, pindel, varscan2
- LYZL2 | c.320C>T p.A107V (on ENST00000375318; = p.A61V on NM_183058.3) | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- MROH2B | c.775A>T p.T259S | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NDN | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- NUP160 | c.4039T>G p.L1347V | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- OR13D1 | c.943C>A p.P315T | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR13D1 | c.944C>G p.P315R | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PBRM1 | c.818C>A p.A273E | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDHGA4 | c.1358dup p.T454Nfs*4 | Frame Shift Ins (INS) | VAF 16/88 reads (18%) | called by mutect2, pindel, varscan2
- PIKFYVE | c.742C>A p.P248T | Missense Mutation (SNP) | VAF 60/212 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SMC4 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SV2A | c.619del p.L207* | Frame Shift Del (DEL) | VAF 20/74 reads (27%) | called by mutect2, pindel, varscan2
- TRIO | c.1386T>G p.D462E | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPC7 | c.2127del p.F709Lfs*3 | Frame Shift Del (DEL) | VAF 28/146 reads (19%) | called by mutect2, pindel, varscan2
- TTLL13P | c.2380C>T p.L794F | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- ZNF350 | c.1163A>T p.K388M | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- BCOR | c.1321C>T p.L441= | Silent (SNP) | VAF 150/617 reads (24%) | catalogued as COSV60702862; called by muse, mutect2, varscan2
- CEP78 | c.1389G>A p.L463= (on ENST00000424347 / NM_001349840.2; = p.L464= on NM_032171.3) | Silent (SNP) | VAF 4/31 reads (13%) | called by muse, varscan2
- CHD9 | c.2946C>T p.G982= | Silent (SNP) | VAF 72/327 reads (22%) | called by muse, mutect2, varscan2
- ECD | c.1032T>C p.D344= | Silent (SNP) | VAF 21/86 reads (24%) | called by muse, mutect2, varscan2
- EEF1E1 | c.66C>T p.Y22= | Silent (SNP) | VAF 35/150 reads (23%) | called by muse, mutect2, varscan2
- FAT1 | c.7059C>A p.S2353= | Silent (SNP) | VAF 70/289 reads (24%) | called by muse, mutect2, varscan2
- MACF1 | c.7350T>A p.A2450= | Silent (SNP) | VAF 28/117 reads (24%) | called by muse, mutect2, varscan2
- NFATC2 | c.747T>C p.G249= | Silent (SNP) | VAF 45/213 reads (21%) | catalogued as COSV65356595; called by muse, mutect2, varscan2
- NRSN1 | c.249C>T p.G83= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as rs140489181; called by muse, mutect2, varscan2
- PKHD1 | c.7872A>G p.S2624= | Silent (SNP) | VAF 37/144 reads (26%) | catalogued as rs1446607271; called by muse, mutect2, varscan2
- SH2D2A | c.243C>A p.T81= | Silent (SNP) | VAF 44/136 reads (32%) | called by muse, mutect2, varscan2
- STARD8 | c.2523G>C p.V841= | Silent (SNP) | VAF 68/245 reads (28%) | called by muse, mutect2, varscan2
- TMPRSS9 | c.3105C>T p.G1035= (on ENST00000648592; = p.G1001= on NM_182973.2) | Silent (SNP) | VAF 44/162 reads (27%) | catalogued as rs1300920785; called by muse, mutect2, varscan2
- YIPF3 | c.159G>C p.L53= | Silent (SNP) | VAF 41/179 reads (23%) | called by muse, mutect2, varscan2
- COMMD4P1 | n.338A>G | RNA (SNP) | VAF 16/93 reads (17%) | catalogued as rs1403090287; called by muse, mutect2, varscan2
- DOCK6 | c.*23C>T | 3'UTR (SNP) | VAF 40/203 reads (20%) | catalogued as rs753002305; called by muse, mutect2, varscan2
- GORASP2 | c.-27G>A | 5'UTR (SNP) | VAF 4/48 reads (8%) | catalogued as rs969673091; called by muse, mutect2
- HUWE1 | c.8206+129G>T | Intron (SNP) | VAF 17/87 reads (20%) | called by muse, mutect2, varscan2
- LDHA | c.*480T>C | 3'UTR (SNP) | VAF 15/58 reads (26%) | called by muse, mutect2, varscan2
- POU2F2 | c.186+25G>A | Intron (SNP) | VAF 49/252 reads (19%) | called by muse, mutect2, varscan2
- PSG8 | chr19:42753364 G>A | 3'Flank (SNP) | VAF 35/310 reads (11%) | catalogued as rs758343639; called by muse, mutect2, varscan2
- TCF4 | c.305-26C>A | Intron (SNP) | VAF 76/294 reads (26%) | called by muse, mutect2, varscan2
- WWC1 | c.2917-17dup | Intron (INS) | VAF 38/114 reads (33%) | called by mutect2, pindel, varscan2
